Somatic mutation profile of tumor specimen C3N-03886-03 (aliquot CPT0221650006) from CPTAC case C3N-03886, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: GX; Age at diagnosis: 60.3 years (22,042 days).
Specimen C3N-03886-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 592dfcb8-52ea-4c4c-a1a3-61686f01519b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03886-71 (Blood Derived Normal), aliquot CPT0221750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e27f419-a625-4051-ad6c-6a03111eb967

The open-access MAF lists 303 somatic variants for this specimen: 195 protein-altering or splice-affecting, 71 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 71, Intron 17, Nonsense Mutation 8, Frame Shift Del 8, 3'UTR 6, 5'UTR 6, RNA 5, Splice Region 5, 5'Flank 3, Splice Site 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 22/503 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 626/759 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAT3 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 139/311 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as rs1000485286; called by muse, mutect2, varscan2
- AKAP6 | c.5038A>G p.I1680V | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1283926019; called by muse, mutect2, varscan2
- AKNA | c.2650C>T p.Q884* | Nonsense Mutation (SNP) | VAF 47/157 reads (30%) | catalogued as COSV56312716; called by muse, mutect2, varscan2
- ANKRD17 | c.3355C>G p.P1119A | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV58216204; called by muse, mutect2, varscan2
- BICD1 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as COSV55683530; called by muse, mutect2, varscan2
- C5orf22 | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100323567; called by muse, mutect2, varscan2
- C8orf34 | c.1004C>A p.A335D | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61388975; called by muse, mutect2, varscan2
- CACUL1 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100432444; called by muse, mutect2, varscan2
- CD1C | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 136/923 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV63805583; called by muse, mutect2, varscan2
- CFAP99 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs950863894; called by muse, mutect2, varscan2
- DEFB110 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV64484503; called by muse, mutect2, varscan2
- EMILIN3 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762559428; called by muse, mutect2
- EYS | c.3136T>C p.C1046R | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV65545129; called by muse, mutect2, varscan2
- FMNL1 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 160/336 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV58957462; called by muse, mutect2, varscan2
- FOXC1 | c.821del p.P274Rfs*41 | Frame Shift Del (DEL) | VAF 178/920 reads (19%) | catalogued as CX117371; called by mutect2, pindel, varscan2
- FRMD3 | c.1530G>C p.W510C | Missense Mutation (SNP) | VAF 150/362 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1432622575; called by muse, mutect2
- FZD6 | c.1733A>G p.H578R | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs775395889; called by muse, mutect2, varscan2
- GAS2L3 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57157423; called by muse, mutect2, varscan2
- GRIN2A | c.1448G>C p.G483A | Missense Mutation (SNP) | VAF 23/345 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58061852; called by muse, mutect2
- HTR2C | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.543); catalogued as COSV99349573; called by muse, mutect2, varscan2
- IPO7 | c.2098del p.Y700Mfs*2 | Frame Shift Del (DEL) | VAF 37/132 reads (28%) | catalogued as COSV65686203; called by mutect2, pindel, varscan2
- KMT2B | c.6448C>G p.Q2150E | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV55860908; called by muse, mutect2, varscan2
- LAMA2 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV101370949; called by muse, mutect2, varscan2
- MVP | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs770280110, COSV62423031; called by muse, mutect2
- MYO3A | c.4039G>A p.D1347N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.341); catalogued as COSV56350834; called by muse, mutect2, varscan2
- NCAPD2 | c.3584C>G p.S1195C | Missense Mutation (SNP) | VAF 11/325 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV57522112; called by muse, mutect2
- NFYB | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as rs769850922; called by muse, mutect2, varscan2
- NIPSNAP2 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs374907292; called by muse, mutect2, varscan2
- NOTCH1 | c.2235G>T p.W745C | Missense Mutation (SNP) | VAF 38/491 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53097211; called by muse, mutect2
- NPR1 | c.584A>G p.H195R | Missense Mutation (SNP) | VAF 183/914 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs768922630; called by muse, mutect2, varscan2
- OASL | c.1312G>C p.V438L | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV56566626; called by muse, mutect2, varscan2
- OPLAH | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV70677110; called by muse, mutect2, varscan2
- OR13A1 | c.259A>G p.M87V | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs771761970; called by muse, mutect2, varscan2
- OR4C11 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV56354997; called by muse, mutect2, varscan2
- PCDHB10 | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 297/407 reads (73%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs77535010, COSV99503823; called by muse, mutect2, varscan2
- PDE3B | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as COSV99962879; called by muse, mutect2, varscan2
- PER2 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs778141128, COSV54522500; called by muse, mutect2, varscan2
- PEX5L | c.968T>A p.F323Y | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV55845479; called by muse, mutect2
- RB1 | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 41/62 reads (66%) | catalogued as CM961237, COSV57299350; called by muse, mutect2, varscan2
- RRM2 | n.359G>T | Splice Region (SNP) | VAF 152/455 reads (33%) | catalogued as rs1356057859; called by muse, mutect2, varscan2
- RYR3 | c.10453G>T p.A3485S (on ENST00000389232; = p.A3486S on NM_001036.6) | Missense Mutation (SNP) | VAF 138/358 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66777358; called by muse, mutect2, varscan2
- SDCBP2 | c.198C>G p.S66R | Missense Mutation (SNP) | VAF 104/268 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV60590947; called by muse, mutect2, varscan2
- SEMA4D | c.2370G>T p.K790N | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV59394174; called by muse, mutect2, varscan2
- SKAP1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 160/425 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs761604918, COSV61145889; called by muse, mutect2, varscan2
- SLC45A1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 448/539 reads (83%) | SIFT tolerated (0.7); PolyPhen benign (0.112); catalogued as rs1232165302; called by muse, mutect2, varscan2
- SPATA31D1 | c.4255C>T p.H1419Y | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1250054678; called by muse, mutect2, varscan2
- SPTA1 | c.5270G>T p.R1757L | Missense Mutation (SNP) | VAF 55/1315 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779823270, COSV63750484; called by muse, mutect2
- TAS2R10 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV104383629; called by muse, mutect2, varscan2
- TBC1D24 | c.1453G>A p.A485T (on ENST00000646147 / NM_001199107.2; = p.A479T on NM_020705.3) | Missense Mutation (SNP) | VAF 197/535 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs774586263, COSV53547876; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TH | c.1417G>A p.D473N (on ENST00000381178 / NM_199292.3; = p.D442N on NM_000360.4) | Missense Mutation (SNP) | VAF 136/458 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775587609, COSV99171125; called by muse, mutect2, varscan2
- TNN | c.3345del p.N1116Tfs*22 | Frame Shift Del (DEL) | VAF 117/791 reads (15%) | catalogued as COSV104382293; called by mutect2, pindel, varscan2
- TOX4 | c.1649C>G p.S550C | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.712); catalogued as COSV99398372; called by muse, mutect2
- USP6NL | c.2000C>G p.S667C | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as rs1356238780; called by muse, mutect2
- ZIC4 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 171/1072 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as rs769358963, COSV67172922; called by muse, mutect2, varscan2
- ZNF160 | c.250T>C p.C84R | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as rs1568480948; called by muse, mutect2, varscan2
- ZNF479 | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100482628; called by muse, mutect2, varscan2
- ZNF559 | c.1511G>A p.R504Q | Missense Mutation (SNP) | VAF 18/315 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.56); catalogued as rs759877245; called by muse, mutect2
- ZNF98 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV63337788, COSV63340728; called by muse, mutect2, varscan2
- ADAM30 | c.901T>A p.Y301N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- ADAMTS12 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP6 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- AL645922.1 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 81/731 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANKRD36 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- AP002512.3 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ARAP1 | c.1022G>T p.G341V (on ENST00000393609 / NM_001040118.2; = p.G96V on NM_015242.4) | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ATP13A2 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2
- ATR | c.6037A>G p.T2013A | Missense Mutation (SNP) | VAF 117/164 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BCKDHB | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BDH1 | c.767T>C p.I256T | Missense Mutation (SNP) | VAF 51/375 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BPTF | c.6956G>T p.G2319V | Missense Mutation (SNP) | VAF 26/649 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C12orf40 | c.891C>G p.D297E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C1orf94 | c.1648A>T p.M550L (on ENST00000488417 / NM_001134734.2; = p.M360L on NM_032884.5) | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASZ1 | c.4366C>T p.H1456Y | Missense Mutation (SNP) | VAF 50/780 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CATSPER1 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDHR2 | c.2732dup p.N911Kfs*9 | Frame Shift Ins (INS) | VAF 41/75 reads (55%) | called by mutect2, pindel, varscan2
- CFAP54 | c.6621del p.Y2208Tfs*4 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | called by mutect2, pindel, varscan2
- CIT | c.1837-2A>C p.X613_splice | Splice Site (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2575G>T p.V859L | Missense Mutation (SNP) | VAF 132/346 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- COL6A3 | c.1772A>T p.E591V | Missense Mutation (SNP) | VAF 181/339 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CPNE7 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 170/200 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.1042T>A p.L348M | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DCDC2B | c.38T>A p.V13E | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DHX36 | c.1825G>A p.G609S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.4848G>T p.E1616D | Missense Mutation (SNP) | VAF 69/91 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DRD3 | c.836A>T p.E279V | Missense Mutation (SNP) | VAF 169/550 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DST | c.5854C>T p.L1952F | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DYNC1H1 | c.3056A>G p.Y1019C | Missense Mutation (SNP) | VAF 180/349 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DYNC1H1 | c.11943A>G p.T3981= | Splice Region (SNP) | VAF 215/496 reads (43%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.12902+1G>A p.X4301_splice | Splice Site (SNP) | VAF 184/629 reads (29%) | called by muse, mutect2, varscan2
- EBAG9 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF4A3 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENOSF1 | c.233C>G p.T78R (on ENST00000340116 / NM_001354066.2; = p.T30R on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- FADS1 | c.1264A>G p.N422D | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FAM135B | c.3991A>T p.T1331S | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2
- FAM186A | c.1479C>A p.Y493* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- FAM216B | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FANCC | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FAT4 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 130/170 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT4 | c.8525G>T p.R2842L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FH | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLRT2 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FREM1 | c.6136A>G p.K2046E | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- FREM3 | c.2048C>A p.P683H | Missense Mutation (SNP) | VAF 189/244 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FSIP2 | c.6020C>T p.A2007V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- GABRA1 | c.710A>G p.Y237C | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRR3 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 111/447 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GFM1 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 113/518 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLDC | c.2954C>A p.T985K | Missense Mutation (SNP) | VAF 185/473 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- GPR4 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT tolerated (0.51); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- H2BC14 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 100/323 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- H2BW2 | c.282C>A p.D94E | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2
- HECTD4 | c.13055C>A p.P4352H | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HECW2 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- HINT1 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- HNRNPA3 | c.966C>G p.N322K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- HYDIN | c.5748G>T p.Q1916H | Missense Mutation (SNP) | VAF 112/328 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IDO1 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- IGHV1-18 | c.158T>A p.I53N | Missense Mutation (SNP) | VAF 206/653 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- IGKV1-16 | c.268G>T p.G90W | Missense Mutation (SNP) | VAF 343/827 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- KAT2B | c.2202C>A p.S734R | Missense Mutation (SNP) | VAF 95/283 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- KCNS1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 145/310 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- KIF26B | c.5238_5239del p.G1747Pfs*241 | Frame Shift Del (DEL) | VAF 80/300 reads (27%) | called by pindel, varscan2
- KIFC2 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 96/273 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LETM2 | c.1003G>A p.V335M (on ENST00000379957 / NM_001286819.2; = p.V240M on NM_144652.3) | Missense Mutation (SNP) | VAF 112/168 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MAB21L3 | c.1021A>T p.T341S | Missense Mutation (SNP) | VAF 210/290 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPKBP1 | c.839C>A p.T280N (on ENST00000456763 / NM_001128608.2; = p.T274N on NM_014994.3) | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2
- MCM2 | c.619G>T p.V207F | Missense Mutation (SNP) | VAF 105/523 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MIA2 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 227/568 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- MPP7 | c.888-2A>C p.X296_splice | Splice Site (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- MYRFL | c.2043A>C p.S681= | Splice Region (SNP) | VAF 41/228 reads (18%) | called by muse, mutect2, varscan2
- NEURL4 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- NLRP12 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 238/318 reads (75%) | called by muse, mutect2, varscan2
- NUP160 | c.3703T>G p.F1235V | Missense Mutation (SNP) | VAF 96/288 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NXPH1 | c.274A>G p.R92G | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OLFM2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 103/244 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2AG2 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 166/368 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR51V1 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR52K1 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 109/321 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- OR5T1 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- OR8I2 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, varscan2
- OTOGL | c.6223T>A p.C2075S (on ENST00000547103; = p.C2066S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PALD1 | c.870G>T p.R290= | Splice Region (SNP) | VAF 168/264 reads (64%) | called by muse, mutect2, varscan2
- PCNX4 | c.2242G>A p.D748N (on ENST00000406854 / NM_001330177.2; = p.D514N on NM_022495.5) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEMT | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PEX14 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 598/725 reads (82%) | called by muse, mutect2, varscan2
- PIWIL1 | c.1161C>A p.C387* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2
- PLXND1 | c.4196C>T p.P1399L | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PON3 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 38/415 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- POP4 | c.444del p.S149Lfs*26 | Frame Shift Del (DEL) | VAF 114/214 reads (53%) | called by mutect2, pindel, varscan2
- POTEE | c.1613C>A p.A538D | Missense Mutation (SNP) | VAF 265/617 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- PPP1R16B | c.1503C>A p.H501Q | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PRR23A | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 658/791 reads (83%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- PRTG | c.90G>T p.L30F | Missense Mutation (SNP) | VAF 251/631 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYGO1 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- RBM33 | c.2182G>T p.A728S | Missense Mutation (SNP) | VAF 86/332 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RERE | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 461/581 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- REST | c.1495G>C p.V499L | Missense Mutation (SNP) | VAF 35/453 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- RTEL1 | c.2896G>A p.E966K | Missense Mutation (SNP) | VAF 148/404 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SCN7A | c.1544T>G p.I515R | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SEC24D | c.1359A>G p.I453M | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SEPTIN3 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 177/422 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SETMAR | c.1408A>C p.N470H | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.96); called by muse, varscan2
- SGCD | c.83G>C p.G28A (on ENST00000435422 / NM_001128209.2; = p.G29A on NM_000337.5) | Missense Mutation (SNP) | VAF 89/136 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMG1 | c.2545A>G p.M849V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SPHKAP | c.2783A>T p.D928V | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SPOCK2 | c.592A>T p.T198S | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SYT13 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF8 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TBC1D16 | c.1671G>C p.L557F | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TECR | c.384-6G>A | Splice Region (SNP) | VAF 335/844 reads (40%) | called by muse, mutect2, varscan2
- THBS1 | c.3362T>G p.I1121S | Missense Mutation (SNP) | VAF 103/223 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRADD | c.825_844del p.E276Afs*77 | Frame Shift Del (DEL) | VAF 233/349 reads (67%) | called by mutect2, pindel, varscan2
- TRIM3 | c.1714G>C p.A572P | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- TRIM48 | c.111C>A p.Y37* | Nonsense Mutation (SNP) | VAF 67/560 reads (12%) | called by muse, mutect2, varscan2
- UQCRQ | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 160/219 reads (73%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VWA5B1 | c.373C>G p.R125G | Missense Mutation (SNP) | VAF 362/462 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWF | c.7423G>T p.D2475Y | Missense Mutation (SNP) | VAF 222/627 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- WIF1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- XRN2 | c.479_486+3del | Frame Shift Del (DEL) | VAF 31/129 reads (24%) | called by mutect2, pindel, varscan2
- ZBTB43 | c.485A>T p.H162L | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFHX4 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 68/190 reads (36%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.2750G>T p.C917F | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF136 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF26 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 94/245 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- ZNF490 | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ZNF592 | c.1210T>G p.S404A | Missense Mutation (SNP) | VAF 82/493 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF599 | c.786A>T p.K262N | Missense Mutation (SNP) | VAF 92/361 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF716 | c.1285A>T p.I429F | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, varscan2
- ZNF727 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ZNF775 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 249/325 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF804A | c.2101A>T p.N701Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ZNF831 | c.1969G>C p.G657R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ZNF91 | c.2718A>T p.R906S | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- ABCA7 | c.2215C>T p.L739= | Silent (SNP) | VAF 38/555 reads (7%) | called by muse, mutect2
- ATP1A3 | c.1785C>T p.I595= (on ENST00000545399 / NM_001256214.2; = p.I582= on NM_152296.5) | Silent (SNP) | VAF 219/279 reads (78%) | catalogued as rs781992944, COSV100132480, COSV57491495; called by muse, mutect2, varscan2
- BCHE | c.756T>C p.S252= | Silent (SNP) | VAF 61/228 reads (27%) | called by muse, mutect2, varscan2
- BRCC3 | c.696A>G p.A232= | Silent (SNP) | VAF 93/125 reads (74%) | called by muse, mutect2, varscan2
- BRDT | c.720G>A p.V240= | Silent (SNP) | VAF 47/124 reads (38%) | catalogued as rs1483048906; called by muse, mutect2, varscan2
- BZW2 | c.522C>T p.T174= | Silent (SNP) | VAF 36/554 reads (6%) | catalogued as rs377669851; called by muse, mutect2
- C10orf71 | c.1344C>A p.T448= | Silent (SNP) | VAF 166/269 reads (62%) | called by muse, mutect2, varscan2
- C12orf45 | c.192G>A p.E64= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs1200501427; called by muse, mutect2, varscan2
- CACNA1E | c.2040C>T p.A680= | Silent (SNP) | VAF 67/100 reads (67%) | catalogued as rs1558306359; called by muse, mutect2, varscan2
- CDH23 | c.384C>T p.N128= | Silent (SNP) | VAF 52/340 reads (15%) | catalogued as rs766060083, COSV54929498; called by muse, mutect2, varscan2
- CDS2 | c.750A>G p.P250= | Silent (SNP) | VAF 99/250 reads (40%) | called by muse, mutect2, varscan2
- CFAP46 | c.2355G>T p.T785= | Silent (SNP) | VAF 129/186 reads (69%) | called by muse, mutect2, varscan2
- CLCN7 | c.1269C>T p.V423= | Silent (SNP) | VAF 60/797 reads (8%) | called by muse, mutect2
- COX10 | c.1071G>T p.A357= | Silent (SNP) | VAF 93/213 reads (44%) | called by muse, mutect2, varscan2
- CSMD3 | c.10452C>A p.P3484= (on ENST00000297405 / NM_001363185.1; = p.P3315= on NM_052900.3) | Silent (SNP) | VAF 99/242 reads (41%) | catalogued as COSV52105482, COSV52110613, COSV52334547; called by muse, mutect2, varscan2
- CYP2S1 | c.1065G>T p.A355= | Silent (SNP) | VAF 123/189 reads (65%) | catalogued as rs542005816, COSV59505765; called by muse, mutect2, varscan2
- DAAM1 | c.1566C>T p.A522= | Silent (SNP) | VAF 62/184 reads (34%) | catalogued as rs765736106, COSV62836791; called by muse, varscan2
- DBF4B | c.537G>T p.V179= | Silent (SNP) | VAF 94/263 reads (36%) | called by muse, mutect2, varscan2
- DOCK10 | c.6213T>C p.A2071= | Silent (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- DONSON | c.57G>A p.V19= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- EFR3B | c.534G>T p.T178= | Silent (SNP) | VAF 93/242 reads (38%) | called by muse, mutect2, varscan2
- EIF3B | c.2415A>G p.E805= | Silent (SNP) | VAF 117/250 reads (47%) | catalogued as rs1243765450; called by muse, mutect2, varscan2
- ELMO1 | c.2067G>C p.L689= | Silent (SNP) | VAF 189/550 reads (34%) | catalogued as COSV60296185; called by muse, mutect2, varscan2
- EPAS1 | c.2199A>G p.S733= | Silent (SNP) | VAF 243/617 reads (39%) | called by muse, mutect2, varscan2
- EPHA5 | c.1389C>A p.T463= | Silent (SNP) | VAF 45/64 reads (70%) | called by muse, mutect2, varscan2
- FANCM | c.5268C>G p.V1756= | Silent (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- FARP1 | c.729C>T p.A243= | Silent (SNP) | VAF 177/235 reads (75%) | catalogued as rs770432717, COSV60349172; called by muse, mutect2, varscan2
- FGF2 | c.126C>T p.L42= | Silent (SNP) | VAF 99/135 reads (73%) | called by muse, mutect2, varscan2
- FREM3 | c.6126A>G p.Q2042= | Silent (SNP) | VAF 112/153 reads (73%) | catalogued as rs550885441; called by muse, mutect2, varscan2
- GALNT13 | c.270G>A p.L90= | Silent (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- GHSR | c.399C>T p.T133= | Silent (SNP) | VAF 211/812 reads (26%) | called by muse, mutect2, varscan2
- HECTD1 | c.6603T>C p.D2201= | Silent (SNP) | VAF 40/136 reads (29%) | called by muse, mutect2, varscan2
- HOXB4 | c.249C>A p.P83= | Silent (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- HTRA1 | c.426G>T p.L142= | Silent (SNP) | VAF 458/621 reads (74%) | called by muse, mutect2, varscan2
- KCNS1 | c.777G>T p.A259= | Silent (SNP) | VAF 146/314 reads (46%) | catalogued as rs1250772653; called by muse, mutect2, varscan2
- MAF | c.900C>T p.G300= | Silent (SNP) | VAF 61/567 reads (11%) | called by muse, mutect2, varscan2
- MYLK | c.3618C>G p.P1206= | Silent (SNP) | VAF 42/398 reads (11%) | called by muse, mutect2, varscan2
- NALCN | c.138C>T p.A46= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1415238686, COSV51953092; called by muse, mutect2
- NEURL4 | c.2013C>T p.V671= | Silent (SNP) | VAF 100/266 reads (38%) | catalogued as rs367715778; called by muse, mutect2, varscan2
- NTSR1 | c.192G>T p.V64= | Silent (SNP) | VAF 165/410 reads (40%) | called by muse, mutect2, varscan2
- OR1D5 | c.492C>G p.T164= | Silent (SNP) | VAF 456/589 reads (77%) | catalogued as COSV73859538; called by muse, mutect2, varscan2
- OR1S1 | c.750C>T p.A250= | Silent (SNP) | VAF 106/212 reads (50%) | catalogued as rs1292971667; called by muse, mutect2, varscan2
- OR4A16 | c.495A>G p.P165= | Silent (SNP) | VAF 116/258 reads (45%) | called by muse, mutect2, varscan2
- OR4C11 | c.114G>A p.V38= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- OR5I1 | c.27G>C p.T9= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100041374; called by muse, varscan2
- OR6Q1 | c.69T>C p.H23= | Silent (SNP) | VAF 79/204 reads (39%) | called by muse, mutect2, varscan2
- PAX7 | c.595C>T p.L199= | Silent (SNP) | VAF 284/333 reads (85%) | called by muse, mutect2, varscan2
- PDE1C | c.1791A>T p.S597= | Silent (SNP) | VAF 94/264 reads (36%) | called by muse, mutect2, varscan2
- PLPP5 | c.93C>T p.P31= | Silent (SNP) | VAF 54/81 reads (67%) | called by muse, mutect2, varscan2
- PNPLA6 | c.2004C>T p.I668= (on ENST00000414982 / NM_001166111.2; = p.I620= on NM_006702.5) | Silent (SNP) | VAF 280/685 reads (41%) | called by muse, mutect2, varscan2
- PRPS2 | c.201G>A p.L67= | Silent (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- PRRC2B | c.1902A>G p.Q634= | Silent (SNP) | VAF 81/155 reads (52%) | catalogued as rs375441747; called by muse, mutect2, varscan2
- PTPRD | c.3405G>A p.E1135= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as rs1421891744; called by mutect2, varscan2
- RIN3 | c.630C>A p.L210= | Silent (SNP) | VAF 88/265 reads (33%) | catalogued as COSV53647882; called by muse, mutect2, varscan2
- RNF6 | c.804G>A p.R268= | Silent (SNP) | VAF 113/250 reads (45%) | catalogued as COSV100644571; called by muse, mutect2, varscan2
- SETMAR | c.1359G>A p.V453= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, varscan2
- SLC24A5 | c.735G>A p.Q245= | Silent (SNP) | VAF 30/319 reads (9%) | called by muse, mutect2, varscan2
- SLC25A3 | c.504C>G p.A168= (on ENST00000228318 / NM_005888.3; = p.A167= on NM_002635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 137/292 reads (47%) | catalogued as rs1352337833, COSV99499507; called by muse, mutect2, varscan2
- SPATA18 | c.468G>T p.S156= | Silent (SNP) | VAF 33/191 reads (17%) | catalogued as COSV54645355, COSV54645683; called by muse, mutect2, varscan2
- STXBP5 | c.477G>T p.V159= | Silent (SNP) | VAF 85/152 reads (56%) | called by muse, mutect2, varscan2
- SUSD2 | c.1638G>T p.L546= | Silent (SNP) | VAF 107/337 reads (32%) | catalogued as COSV64203858, COSV64204596; called by muse, mutect2, varscan2
- TENM4 | c.5109G>A p.L1703= | Silent (SNP) | VAF 24/741 reads (3%) | called by muse, mutect2
- TLR4 | c.969A>T p.V323= (on ENST00000355622 / NM_138554.5; = p.V283= on NM_003266.4) | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV100790668; called by muse, mutect2, varscan2
- TMEM131 | c.39C>T p.T13= | Silent (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- TMEM94 | c.858C>T p.P286= | Silent (SNP) | VAF 217/470 reads (46%) | catalogued as rs368314581; called by muse, mutect2, varscan2
- TOR4A | c.357G>A p.A119= | Silent (SNP) | VAF 58/390 reads (15%) | catalogued as COSV62627269; called by muse, mutect2, varscan2
- TREX1 | c.744C>T p.V248= (on ENST00000625293 / NM_033629.6; = p.V238= on NM_007248.5) | Silent (SNP) | VAF 113/525 reads (22%) | called by muse, mutect2, varscan2
- TRPS1 | c.2994C>A p.L998= (on ENST00000220888 / NM_001330599.2; = p.L1011= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- TTN | c.100167C>T p.D33389= (on ENST00000591111; = p.D25965= on NM_003319.4) | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as rs72629789, COSV60461316; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- UGT8 | c.1497C>A p.I499= | Silent (SNP) | VAF 52/72 reads (72%) | called by muse, mutect2, varscan2
- ZFP64 | c.837G>C p.R279= | Silent (SNP) | VAF 110/264 reads (42%) | called by muse, mutect2, varscan2
- ACTN1 | c.2361+223G>T | Intron (SNP) | VAF 83/208 reads (40%) | called by muse, mutect2, varscan2
- AMT | c.*317G>A | 3'UTR (SNP) | VAF 92/111 reads (83%) | called by muse, mutect2, varscan2
- APOL4 | c.44+290_44+292dup | Intron (INS) | VAF 57/487 reads (12%) | called by mutect2, pindel, varscan2
- C17orf49 | c.-53C>G | 5'UTR (SNP) | VAF 38/506 reads (8%) | called by muse, mutect2
- C4B | chr6:32010712 C>G | 5'Flank (SNP) | VAF 55/278 reads (20%) | called by muse, mutect2, varscan2
- C8orf76 | c.-14G>A | 5'UTR (SNP) | VAF 87/208 reads (42%) | catalogued as COSV99415202; called by muse, mutect2, varscan2
- CERS5 | c.198-10189C>G | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- CSTF3 | c.*81G>A | 3'UTR (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- DAAM2 | c.*2632C>T | 3'UTR (SNP) | VAF 99/224 reads (44%) | called by muse, mutect2, varscan2
- EFHC1 | c.724-318A>T | Intron (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2, varscan2
- ETNK2 | c.519-177T>C | Intron (SNP) | VAF 152/363 reads (42%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105399073 C>A | 5'Flank (SNP) | VAF 164/354 reads (46%) | catalogued as rs111754570; called by muse, mutect2, varscan2
- FRG2KP | chr16:31569300 G>T | 5'Flank (SNP) | VAF 200/456 reads (44%) | called by muse, mutect2, varscan2
- HSD17B7P2 | n.410C>G | RNA (SNP) | VAF 49/98 reads (50%) | called by muse, varscan2
- IL20RB | c.88+11081G>T | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- ITGA4 | c.*1516A>G | 3'UTR (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- KIAA2012 | c.369+1772G>A | Intron (SNP) | VAF 43/124 reads (35%) | called by mutect2, varscan2
- LINC01135 | n.629A>C | RNA (SNP) | VAF 118/176 reads (67%) | called by muse, mutect2, varscan2
- LINC01193 | n.1450T>C | RNA (SNP) | VAF 112/758 reads (15%) | called by muse, mutect2, varscan2
- LMF1 | c.1416+341G>A | Intron (SNP) | VAF 111/235 reads (47%) | called by muse, mutect2, varscan2
- LRRC37A4P | n.5278A>G | RNA (SNP) | VAF 134/414 reads (32%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12892T>C | Intron (SNP) | VAF 65/175 reads (37%) | called by muse, mutect2, varscan2
- PGPEP1 | c.-54A>G | 5'UTR (SNP) | VAF 130/363 reads (36%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*5G>A | 3'UTR (SNP) | VAF 12/100 reads (12%) | catalogued as rs11585908; called by muse, mutect2
- PYY | c.*69C>T | 3'UTR (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100778852, COSV100779037; called by muse, mutect2, varscan2
- RBFOX1 | c.351+152593C>A | Intron (SNP) | VAF 87/212 reads (41%) | called by muse, mutect2, varscan2
- RBM8A | c.-1G>C | 5'UTR (SNP) | VAF 111/727 reads (15%) | called by muse, mutect2, varscan2
- SPATA21 | c.35-3583C>A | Intron (SNP) | VAF 302/362 reads (83%) | called by muse, mutect2, varscan2
- STAB2 | c.2086-29C>T | Intron (SNP) | VAF 81/246 reads (33%) | catalogued as rs1203428547; called by muse, mutect2, varscan2
- STRA6 | c.180+19G>A | Intron (SNP) | VAF 269/666 reads (40%) | called by muse, mutect2, varscan2
- SYNE2 | c.12381+48A>G | Intron (SNP) | VAF 52/149 reads (35%) | called by muse, mutect2, varscan2
- TPRX2P | n.436C>T | RNA (SNP) | VAF 91/202 reads (45%) | called by muse, mutect2, varscan2
- UNC13B | c.4238-1177A>G | Intron (SNP) | VAF 77/213 reads (36%) | called by muse, mutect2, varscan2
- ZIC4 | c.-16+864C>T | Intron (SNP) | VAF 153/1114 reads (14%) | catalogued as rs1411491712; called by muse, mutect2, varscan2
- ZNF285 | c.-4C>T | 5'UTR (SNP) | VAF 57/101 reads (56%) | catalogued as rs767380662, COSV58408505; called by muse, mutect2, varscan2
- ZNF292 | c.538+4051G>C | Intron (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- ZNF805 | c.-22del | 5'UTR (DEL) | VAF 83/163 reads (51%) | called by mutect2, pindel, varscan2
